Surgical pathology report (de-identified scan), TCGA case TCGA-CN-4741, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-4741-01A (Primary Tumor).

[page 1 of 5]
PATIENT HISTORY:

No clinical history is given..

PRE-OP DIAGNOSIS: Malignant neoplasm on the floor of the mouth.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Bilateral neck dissection.

ADDENDA:

Addendum

PART 7: ANTERIOR MANDIBLE, COMPOSITE RESECTION-

LEFT BONE MARGIN IS FREE OF CARCINOMA.

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:

PART 1: LEFT NECK, LEVEL 1, DISSECTION -

- A. SEVEN BENIGN LYMPH NODES (0/7).
- B. SUBMANDIBULAR GLAND WITH MILD CHRONIC SIALADENITIS.

PART 2: RIGHT NECK, LEVEL 1, DISSECTION -

- A. FOUR BENIGN LYMPH NODES (0/4).
- B. SUBMANDIBULAR GLAND WITH PROMINENT CHRONIC AND ACUTE SIALADENITIS.

PART 3: LEFT NECK, LEVELS 2, 3 AND 4, DISSECTION -
FIFTEEN BENIGN LYMPH NODES (0/18).

PART 4: RIGHT NECK, LEVELS 2, 3 AND 4, DISSECTION -
NINETEEN BENIGN LYMPH NODES (0/19).

PART 5: LEFT LINGUAL NERVE, BIOPSY -
SALIVARY DUCT AND SMALL NERVE, NO TUMOR SEEN.

[page 2 of 5]
Pathology Report

PART 6: RIGHT LINGUAL NERVE, BIOPSY –
LARGE NERVE AND GANGLION, NO TUMOR SEEN.

PART 7: ANTERIOR MANDIBLE, COMPOSITE RESECTION –

- A. INVASIVE SQUAMOUS CELL CARCINOMA, 3.7 CM, MODERATELY DIFFERENTIATED, INVOLVING MANDIBULAR BONE.
- B. PERINEURAL INVASION IS IDENTIFIED.
- C. ONE BENIGN LYMPH NODE (0/1).
- D. ALL MARGINS ARE FREE OF CARCINOMA; CARCINOMA IS <0.1CM FROM POSTERIOR SOFT TISSUE MARGIN. LEFT BONE MARGIN – PENDING DECALCIFICATION (ADDENDUM WILL FOLLOW).
- E. PATHOLOGIC STAGE T4 N0 MX.
-
-

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in seven parts.

Part 1 is labeled with the patient's name initials and "left zone #1", received fresh. It consists of a portion of yellow, lobulated adipose tissue measuring 9.0 x 3.8 x 1.5 cm in greatest dimension. The submandibular salivary gland is identified, measuring 4.2 x 2.2 x 1.5 cm in greatest dimension. It is unremarkable. Several lymph nodes are identified, ranging in size from 0.2 up to 0.6 cm in greatest diameter. The specimen is represented in three cassettes:

- 1A – submandibular gland
- 1B and 1C – lymph nodes.

Part 2 is labeled with the patient's name, initials and "right neck level 1" received fresh. It consists of an irregular portion of yellow, lobulated adipose tissue and rubbery to firm submandibular salivary gland. The specimen measures 5.8 x 4.8 x 1.8 cm in greatest dimension. The submandibular gland measures 3.8 x 1.8 x 1.8 cm in greatest dimension. On section, cut surface is yellow to white and firm upon palpation. Several lymph nodes (four) are identified, ranging in size from 0.3 up to 0.8 cm in diameter. The specimen is represented in two cassettes:

- 2A – submandibular gland
- 2B – lymph nodes.

Part 3 is labeled with the patient's name initials and "left neck zones 2, 3 and 4", received fresh. It consists of an irregular portion of tan-brown, yellow, lobulated adipose tissue, partially covered by tan-brown fascia, measuring 10.0 x 7.2 x 1.8 cm in greatest dimension. No parotid gland is identified. Serial sections reveal multiple lymph nodes, ranging in size from 0.2 up to 2.2 cm in diameter. The largest lymph node is identified in level 3. The specimen is represented in eight cassettes:

- 3A and 3B – level 2
- 3C thru 3E – level 3, cassette 3E contains the largest lymph node
- 3F thru 3H – level 4 lymph nodes.

Part 4 is labeled with the patient's name initials and "right neck zones 2, 3 and 4", received fresh. It consists of an irregular portion of tan-brown, yellow, lobulated adipose tissue, partially covered by tan-brown fascia, measuring 11.0 x 9.8 x 1.8 cm in

[page 3 of 5]
Pathology Report

greatest dimension. No parotid gland is identified. On sectioning, several lymph nodes are identified ranging in size from 0.3 up to 1.1 cm in main diameter. The largest lymph node is identified in level 3. The specimen is represented in seven cassettes:

- 4A-4B – lymph nodes, level 2
- 4C-4E – lymph nodes, level 3
- 4F-4G – lymph nodes, level 4.

Part 5 is labeled with the patient's name, initials [REDACTED] and "left lingual nerve" for intraoperative consultation. It consists of two fragments of tan brown soft tissue, measuring in aggregate 0.2 x 0.2 x 0.1 cm in dimension. The specimen is submitted in total in one cassette labeled 5A.

Part 6 is labeled with the patient's name, initials [REDACTED] and "right lingual nerve" for intraoperative consultation. It consists of an irregular portion of tissue measuring 0.7 x 0.5 x 0.1 cm in greatest dimension. The specimen is submitted in total in one cassette labeled 6A.

Part 7 is labeled with the patient's name, initials [REDACTED] and "anterior composite resection" and is received fresh for intraoperative consultation. It consists of mandibulectomy measuring 7.5 cm in width by 5.2 cm (anterior to posterior) by 3.2 cm (superior to inferior). A portion of mandibular bone measures 9.5 cm in length by 2.4 cm in diameter (left side) and 2.1 cm in diameter (right side). A multinodular tumor is identified, 3.7 x 3.5 x 3.5 cm in greatest dimension. The lesion grossly appears to involve the mucosa and is identified 0.5 cm from the left gingival buccal margin. It is also identified at more than 1.0 cm from other mucosal margins. A deep soft edge as well as the posterior edge consist of portion of tan-brown serrated muscle and appear unremarkable (no tumor identified). The posterior soft margin is inked black and the inferior soft tissue edge is inked blue. The specimen is serially cross sectioned and reveals tumor close to the posterior soft tissue margin (0.2 cm). Also tumor grossly permeates and invades the mandibular bone (cassette 7H). The specimen is represented in fourteen cassettes:

- 7A – left posterior margin
- 7B – left anterior gingival buccal margin
- 7C – right anterior gingival buccal margin
- 7D – right posterior
- 7E – left posterior
- 7F – right bone margin
- 7G – left bone margin
- 7H – tumor permeating/invading bone
- 7I-7K – continuous sections left to medial aspect from superior to inferior
- 7L-7N – continuous section right to medial aspect from superior to inferior.

INTRAOPERATIVE CONSULTATION:

5FS: LEFT LINGUAL NERVE (frozen section) –

- A. BENIGN.
- B. SALIVARY DUCT AND SMALL NERVE, NO TUMOR PRESENT [REDACTED]

6FS: RIGHT LINGUAL NERVE (frozen section) –

- A. BENIGN.
- B. LARGE NERVE, GANGLIA, NO TUMOR PRESENT [REDACTED]).

7FS: ANTERIOR COMPOSITE RESECTION (7AFS-7EFS, frozen section) –

- A. MARGINS OF MUCOSA BENIGN
- B. NO TUMOR PRESENT [REDACTED]

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

[page 4 of 5]
Pathology Report

The following statement applies to all immunohistochemistry, insitu hybridization (ISH & FISH), molecular anatomic pathology, and immunofluorescence testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE:	Resection: anterior composite mandibulectomy
TUMOR SITE:	Oral Cavity
TUMOR SIZE:	Greatest dimension: 3.7 cm
HISTOLOGIC TYPE:	Squamous cell carcinoma, conventional
HISTOLOGIC GRADE:	G2
PATHOLOGIC STAGING (pTNM):	pT4a
	pN0
	Number of regional lymph nodes examined: 46
	Number of regional lymph nodes involved: 0
	pMX
MARGINS:	Margins uninvolved by tumor
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):	Absent
PERINEURAL INVASION:	Present

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Left zone 1

Taken:	[REDACTED]
Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C

Part 2: Right neck level 1

Taken:	[REDACTED]
Stain/cnt	Block
H&E x 1	A
H&E x 1	B

Part 3: Left neck zones 2-4

Taken:	[REDACTED]
Stain/cnt	Block
H&E x 1	A
H&E x 1	B
H&E x 1	C
H&E x 1	D

[page 5 of 5]
Pathology Report

H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H

Part 4: Right neck levels 2-4

Taken: [REDACTED]
Stain/cnt Block

H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G

Part 5: Left lingual nerve

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 AFS

Part 6: Right lingual nerve

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 AFS

Part 7: Anterior composite resection

Taken: [REDACTED]
Stain/cnt Block
H&E x 1 F
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J
H&E x 1 K
H&E x 1 L
H&E x 1 M
H&E x 1 N
H&E x 1 AFS
H&E x 1 BFS
H&E x 1 CFS
H&E x 1 DFS
H&E x 1 EFS

ICD-9 Diagnosis Codes: (None Entered)

Source: NCI Genomic Data Commons file 59759595-e4b3-43bf-89bb-5704237d08e7 (TCGA-CN-4741.63474EF4-C119-45EF-AF0A-E01EEDF8A46B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).